Somatic mutation profile of tumor specimen TCGA-96-A4JK-01A (aliquot TCGA-96-A4JK-01A-11D-A257-08) from TCGA case TCGA-96-A4JK, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.6 years (23,974 days).
Specimen TCGA-96-A4JK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4e82179-bc2a-4adb-bdbd-90eab31de7a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-96-A4JK-10A (Blood Derived Normal), aliquot TCGA-96-A4JK-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1534f68a-a464-45a8-b8f1-873aea049be4

The open-access MAF lists 528 somatic variants for this specimen: 399 protein-altering or splice-affecting, 115 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 342, Silent 115, Nonsense Mutation 25, Frame Shift Del 10, Splice Site 10, RNA 5, In Frame Del 4, Intron 4, Splice Region 3, Frame Shift Ins 3, 5'Flank 3, Nonstop Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTB | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1554329113, COSV100079965; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RIT1 | c.270G>T p.M90I | Missense Mutation (SNP) | VAF 38/66 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs483352822, CM136419, CM148229, COSV64170809, COSV64170843, COSV64170960; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 42/88 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.3934G>C p.D1312H | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.497); catalogued as COSV101036415, COSV101037690; called by muse, mutect2, varscan2
- ABCB5 | c.1387C>G p.H463D (on ENST00000404938 / NM_001163941.2; = p.H18D on NM_178559.6) | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.139); catalogued as COSV99329785; called by muse, varscan2
- ABCF2 | c.1828G>T p.V610L | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99734901; called by muse, mutect2, varscan2
- ACACB | c.5952G>C p.Q1984H | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100623313; called by muse, mutect2, varscan2
- ACSM4 | c.977T>C p.M326T | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV101257406; called by muse, mutect2, varscan2
- ACSS1 | c.1580-1G>T p.X527_splice | Splice Site (SNP) | VAF 28/181 reads (15%) | catalogued as COSV100054091; called by muse, mutect2, varscan2
- ADAMTS19 | c.2728C>A p.L910I | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV99182845; called by muse, mutect2, varscan2
- ADAMTS3 | c.2087A>G p.N696S | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV99712131; called by muse, mutect2, varscan2
- ADCYAP1 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 56/229 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99327653; called by muse, mutect2, varscan2
- ADGRL3 | c.1907C>A p.A636D (on ENST00000506720 / NM_001322402.2; = p.A568D on NM_015236.6) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV100800391; called by muse, mutect2, varscan2
- AFF3 | c.1979C>A p.P660H | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100420153; called by muse, mutect2, varscan2
- AFG1L | c.1427G>T p.G476V | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV100934024; called by muse, mutect2, varscan2
- AHNAK2 | c.12906G>T p.K4302N | Missense Mutation (SNP) | VAF 392/878 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100319020; called by muse, mutect2, varscan2
- AKR1B1 | c.611G>C p.G204A | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV99605422; called by muse, mutect2, varscan2
- ALG5 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 59/117 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766053670, COSV53508290; called by muse, mutect2, varscan2
- AMPH | c.1799C>G p.A600G | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100343762; called by muse, mutect2
- ANKRD12 | c.2197G>A p.D733N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.439); catalogued as rs746855325, COSV100042142; called by muse, mutect2, varscan2
- ANO8 | c.683T>G p.V228G | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV99344996; called by muse, mutect2, varscan2
- APOB | c.3790C>A p.Q1264K | Missense Mutation (SNP) | VAF 65/96 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as COSV99268223; called by muse, mutect2, varscan2
- ARHGAP11A | c.2569G>A p.G857R | Missense Mutation (SNP) | VAF 35/266 reads (13%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV100276896, COSV100276980; called by muse, mutect2, varscan2
- ARHGEF19 | c.191G>T p.R64L | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.334); catalogued as COSV54619153; called by muse, mutect2, varscan2
- ASB15 | c.390A>T p.L130F | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as rs1438545981, COSV99307012; called by muse, mutect2, varscan2
- ATP10A | c.1199A>G p.D400G | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV100791557; called by muse, mutect2, varscan2
- ATP12A | c.1277T>A p.F426Y | Missense Mutation (SNP) | VAF 28/270 reads (10%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); catalogued as COSV99518525; called by muse, mutect2, varscan2
- ATP2C1 | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 33/147 reads (22%) | catalogued as COSV99060023; called by muse, mutect2, varscan2
- ATR | c.2264C>T p.S755F | Missense Mutation (SNP) | VAF 34/233 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100638607; called by muse, mutect2, varscan2
- BBOF1 | c.158A>G p.Y53C | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1247439569, COSV58221672; called by muse, mutect2, varscan2
- BBS10 | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99675633; called by muse, mutect2, varscan2
- BCHE | c.1286C>A p.P429H | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100013010, COSV52262937; called by muse, mutect2, varscan2
- BNIP5 | c.1013G>C p.R338P | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV101465219; called by muse, mutect2, varscan2
- BNIP5 | c.1012C>T p.R338W | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs777148851, COSV71325888; called by muse, mutect2, varscan2
- BPIFB2 | c.111G>A p.V37= | Splice Region (SNP) | VAF 64/176 reads (36%) | catalogued as COSV99401698; called by muse, mutect2, varscan2
- BRCA2 | c.4115T>A p.F1372Y | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.535); catalogued as rs1555283567, COSV101204666; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD4 | c.3178C>T p.R1060C | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs768141679, COSV54593066; called by muse, mutect2, varscan2
- BRPF3 | c.1957G>T p.E653* | Nonsense Mutation (SNP) | VAF 5/63 reads (8%) | catalogued as COSV100326202; called by muse, mutect2
- BSN | c.10507G>A p.E3503K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99609903; called by muse, mutect2, varscan2
- BTBD3 | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 18/188 reads (10%) | catalogued as COSV99656121; called by muse, mutect2
- C1GALT1 | c.525A>G p.I175M | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV99777659; called by muse, mutect2, varscan2
- C1QTNF9B | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101158639; called by muse, mutect2, varscan2
- C1S | c.1333G>C p.D445H | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV100196788; called by muse, mutect2, varscan2
- CANT1 | c.1066C>G p.Q356E | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.06); catalogued as COSV100185388, COSV56605900; called by muse, mutect2, varscan2
- CCDC170 | c.1710G>T p.K570N | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99498883; called by muse, mutect2, varscan2
- CCDC185 | c.1144C>G p.Q382E | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as COSV100838839; called by muse, mutect2, varscan2
- CCDC40 | c.2346G>T p.Q782H | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV100884330; called by muse, mutect2, varscan2
- CCDC40 | c.2347G>T p.E783* | Nonsense Mutation (SNP) | VAF 17/77 reads (22%) | catalogued as COSV100884331, COSV66472804; called by muse, mutect2, varscan2
- CCDC63 | c.305C>G p.T102S | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.359); catalogued as COSV100370642; called by muse, mutect2
- CD109 | c.3097G>T p.V1033L | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV99754683; called by muse, mutect2, varscan2
- CD109 | c.3320C>G p.A1107G | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.621); catalogued as COSV99754685; called by muse, mutect2, varscan2
- CD28 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100142596; called by muse, mutect2, varscan2
- CD38 | c.551C>A p.P184H | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV99883083; called by muse, mutect2, varscan2
- CDH13 | c.1423C>T p.P475S | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99228159, COSV99231355; called by muse, mutect2, varscan2
- CDH17 | c.1975G>T p.D659Y | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99217953; called by muse, mutect2, varscan2
- CDH9 | c.1396C>A p.P466T | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.279); catalogued as rs1269088472, COSV99156722; called by muse, mutect2, varscan2
- CECR2 | c.3413C>G p.P1138R (on ENST00000342247 / NM_001290047.2; = p.P954R on NM_001290046.1) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs200495617, COSV99379167; called by mutect2, varscan2
- CELSR2 | c.1393G>C p.E465Q | Missense Mutation (SNP) | VAF 135/255 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54773479, COSV99604783; called by muse, mutect2, varscan2
- CEP135 | c.358C>A p.L120M | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99954913; called by muse, mutect2, varscan2
- CERS3 | c.867C>G p.I289M | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV99432893; called by muse, mutect2, varscan2
- CFAP91 | c.1858G>T p.V620L | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs776933093, COSV99847522; called by muse, mutect2
- CGNL1 | c.2466G>C p.M822I | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99849212; called by muse, mutect2, varscan2
- CHRM2 | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.516); catalogued as COSV100281993; called by muse, mutect2, varscan2
- CLASRP | c.767A>T p.E256V | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); catalogued as COSV99674163; called by muse, mutect2, varscan2
- CLIC5 | c.1166C>G p.T389S (on ENST00000185206 / NM_001370649.1; = p.T230S on NM_016929.5) | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV99485415; called by muse, mutect2
- CNTNAP5 | c.1535G>T p.C512F | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101444258; called by muse, mutect2, varscan2
- COL28A1 | c.1338G>T p.M446I | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV101258960; called by muse, mutect2, varscan2
- COMMD2 | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 23/225 reads (10%) | catalogued as COSV101511909; called by muse, mutect2
- CPAMD8 | c.1999G>C p.D667H (on ENST00000651564; = p.D620H on NM_015692.5) | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99359837; called by muse, mutect2, varscan2
- CPXCR1 | c.163A>T p.T55S | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV99342433; called by muse, mutect2, varscan2
- CRB1 | c.2501G>C p.G834A | Missense Mutation (SNP) | VAF 39/62 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM1514161, COSV100958084; called by muse, mutect2, varscan2
- CRTC2 | c.1391C>T p.S464F | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100339364; called by muse, mutect2, varscan2
- CTDSP2 | c.355C>A p.P119T | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV101143090; called by muse, mutect2, varscan2
- CTNND2 | c.1450G>T p.A484S | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV100481273, COSV58892684; called by muse, mutect2
- CUBN | c.416A>T p.N139I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100910677; called by muse, mutect2, varscan2
- CUL3 | c.1166C>T p.S389L | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100024795, COSV52369729; called by muse, mutect2, varscan2
- CXCL16 | c.280A>G p.M94V | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as COSV99351834; called by muse, mutect2, varscan2
- CYB561A3 | c.699C>A p.D233E | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99582705; called by muse, mutect2, varscan2
- CYBB | c.1088A>G p.E363G | Missense Mutation (SNP) | VAF 44/71 reads (62%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.803); catalogued as COSV101059828; called by muse, mutect2, varscan2
- CYP11A1 | c.1240C>A p.L414M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV51434296; called by muse, mutect2, varscan2
- CYP4B1 | c.183C>T p.I61= | Splice Region (SNP) | VAF 13/80 reads (16%) | catalogued as COSV99597523; called by muse, mutect2, varscan2
- DAZAP1 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 80/241 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV99245503; called by muse, mutect2, varscan2
- DCTN5 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs373307086; called by muse, mutect2, varscan2
- DCX | c.296A>T p.Q99L | Missense Mutation (SNP) | VAF 67/102 reads (66%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); catalogued as COSV100576774; called by muse, mutect2, varscan2
- DDX60 | c.2297C>A p.T766K | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV101190681; called by muse, mutect2, varscan2
- DENND2C | c.2488G>T p.V830L (on ENST00000393274 / NM_001256404.2; = p.V773L on NM_198459.4) | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101283974; called by muse, mutect2, varscan2
- DENND5B | c.3195G>T p.Q1065H | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.593); catalogued as COSV100172254; called by muse, mutect2
- DHX57 | c.455G>C p.G152A | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.02); catalogued as COSV99768973, COSV99769970; called by muse, mutect2
- DNAH9 | c.2819G>T p.G940V | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV99307183, COSV99308279; called by muse, mutect2, varscan2
- DNAJB8 | c.649T>G p.S217A | Missense Mutation (SNP) | VAF 23/244 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100048506; called by muse, mutect2
- DNAJC14 | c.338C>G p.T113S | Missense Mutation (SNP) | VAF 62/306 reads (20%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV100423740, COSV57914380; called by muse, mutect2, varscan2
- DNAJC5G | c.542G>A p.S181N | Missense Mutation (SNP) | VAF 139/242 reads (57%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99940660; called by muse, mutect2, varscan2
- DOCK10 | c.2984C>G p.A995G | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV99291747; called by muse, mutect2, varscan2
- DSG4 | c.2153C>A p.T718N | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.206); catalogued as COSV100356440; called by muse, mutect2, varscan2
- DTNBP1 | c.277A>T p.S93C | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV100161166; called by muse, mutect2, varscan2
- DZIP1L | c.654G>C p.W218C | Missense Mutation (SNP) | VAF 57/226 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as COSV100551752, COSV59519389; called by muse, mutect2, varscan2
- EAF1 | c.337G>T p.A113S | Missense Mutation (SNP) | VAF 131/290 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.391); catalogued as COSV101112779; called by muse, mutect2, varscan2
- ECSIT | c.1137G>C p.E379D | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.131); catalogued as COSV99369264; called by muse, mutect2, varscan2
- EDNRB | c.812A>G p.Q271R (on ENST00000377211 / NM_001201397.1; = p.Q181R on NM_000115.5) | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV100527118; called by muse, mutect2, varscan2
- EFCC1 | c.1751C>G p.A584G | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.556); catalogued as COSV101460031, COSV71402231; called by muse, mutect2, varscan2
- EFTUD2 | c.2521G>C p.D841H | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99494045; called by muse, mutect2, varscan2
- EMILIN2 | c.1984C>G p.P662A | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV99598935; called by muse, mutect2, varscan2
- EPHA5 | c.1694C>G p.A565G | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.021); catalogued as COSV99901427; called by muse, mutect2, varscan2
- EPSTI1 | c.741A>T p.K247N (on ENST00000398762 / NM_001330543.2; = p.K236N on NM_033255.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/233 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.105); catalogued as COSV100553215; called by muse, mutect2, varscan2
- EXPH5 | c.5672A>C p.K1891T | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99762242; called by muse, mutect2, varscan2
- EXPH5 | c.4796C>G p.S1599C | Missense Mutation (SNP) | VAF 48/201 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.315); catalogued as COSV99762243; called by muse, mutect2, varscan2
- FAM71A | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202026670, COSV99674804; called by muse, mutect2, varscan2
- FAM83C | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.075); catalogued as rs1366767680, COSV100981718; called by muse, mutect2, varscan2
- FBP2 | c.14G>A p.S5N | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.09); catalogued as rs752148715, COSV100942224; called by muse, mutect2, varscan2
- FBXW7 | c.104G>T p.R35L | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.068); catalogued as COSV55903298, COSV99906176; called by muse, varscan2
- FGF7 | c.105G>A p.M35I | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.204); catalogued as COSV99983646; called by muse, mutect2, varscan2
- FIGN | c.1180C>T p.Q394* | Nonsense Mutation (SNP) | VAF 7/126 reads (6%) | catalogued as COSV100293002; called by muse, mutect2
- FMNL3 | c.577G>C p.A193P | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.395); catalogued as COSV99527024; called by muse, mutect2, varscan2
- FOXD4 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 110/324 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100071302; called by muse, varscan2
- FSIP2 | c.19087C>A p.P6363T | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); catalogued as COSV100556625; called by muse, mutect2, varscan2
- FSIP2 | c.20174C>A p.A6725E | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as COSV100556627; called by muse, mutect2
- FUT1 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 49/214 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.532); catalogued as rs1193921269, COSV100038279, COSV59569300; called by muse, mutect2, varscan2
- FYCO1 | c.2193G>T p.R731S | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0.036); catalogued as COSV99946297; called by muse, mutect2, varscan2
- GABRA2 | c.1094A>T p.N365I | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.642); catalogued as COSV100734781; called by muse, mutect2, varscan2
- GABRR2 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 24/477 reads (5%) | catalogued as COSV101299043; called by muse, mutect2
- GALNT8 | c.1016C>G p.P339R | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.317); catalogued as COSV52896802, COSV99362875, COSV99363277; called by muse, mutect2, varscan2
- GAS2L3 | c.951G>A p.M317I | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99903185; called by muse, mutect2, varscan2
- GCC1 | c.2174A>G p.N725S | Missense Mutation (SNP) | VAF 85/243 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100365682; called by muse, mutect2, varscan2
- GHR | c.1060G>C p.D354H | Missense Mutation (SNP) | VAF 122/202 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100052105; called by muse, mutect2, varscan2
- GLMN | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.906); catalogued as COSV100950211; called by muse, mutect2, varscan2
- GPATCH8 | c.3736G>A p.D1246N | Missense Mutation (SNP) | VAF 47/273 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.059); catalogued as rs1269618028, COSV100132881; called by muse, mutect2, varscan2
- GRIN3A | c.1310T>A p.L437Q | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100701858, COSV62453299; called by muse, mutect2, varscan2
- GRM1 | c.2681C>T p.S894L | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV99269155; called by muse, mutect2, varscan2
- GRM8 | c.2657G>A p.C886Y | Missense Mutation (SNP) | VAF 57/197 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1198292954, COSV100285593, COSV100286264; called by muse, mutect2, varscan2
- GTF2IRD2B | c.1879G>T p.A627S | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.023); catalogued as COSV100441280; called by muse, mutect2, varscan2
- GTPBP10 | c.592-1G>T p.X198_splice | Splice Site (SNP) | VAF 38/114 reads (33%) | catalogued as COSV99746257; called by muse, mutect2, varscan2
- GUCA1C | c.629A>T p.*210Lext*2 | Nonstop Mutation (SNP) | VAF 34/90 reads (38%) | catalogued as COSV99659981; called by muse, mutect2, varscan2
- H2BC21 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 170/250 reads (68%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.052); catalogued as COSV100480192; called by muse, mutect2, varscan2
- HAPLN1 | c.721T>C p.W241R | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57150638; called by muse, mutect2, varscan2
- HCN1 | c.2375C>T p.S792L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs140758934, COSV57497778; called by muse, mutect2, varscan2
- HERC1 | c.14256G>T p.Q4752H | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.361); catalogued as COSV101496937; called by muse, mutect2, varscan2
- HERC2 | c.6313G>T p.G2105* | Nonsense Mutation (SNP) | VAF 68/102 reads (67%) | catalogued as COSV99876870; called by muse, mutect2, varscan2
- HERC2 | c.6312G>T p.L2104F | Missense Mutation (SNP) | VAF 66/100 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99876873; called by muse, mutect2, varscan2
- HLA-C | c.548A>T p.Y183F | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100881045; called by muse, mutect2
- HMCN1 | c.6579C>T p.V2193= | Splice Region (SNP) | VAF 16/85 reads (19%) | catalogued as COSV99636186; called by muse, mutect2, varscan2
- HPS4 | c.1423G>C p.D475H | Missense Mutation (SNP) | VAF 41/240 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); catalogued as COSV100404725; called by muse, mutect2, varscan2
- HRG | c.1039A>T p.S347C | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.431); catalogued as COSV99215090; called by muse, mutect2, varscan2
- HS3ST5 | c.125C>A p.P42H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100451430; called by muse, mutect2, varscan2
- HTR2C | c.815C>A p.A272D | Missense Mutation (SNP) | VAF 81/146 reads (55%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV99351104; called by muse, mutect2, varscan2
- HYDIN | c.13218C>G p.I4406M | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV101125230; called by muse, mutect2, varscan2
- IGDCC4 | c.2303T>A p.L768H | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100733169; called by muse, mutect2, varscan2
- IGHV4-28 | c.13T>A p.W5R | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); catalogued as rs782356152; called by muse, mutect2, varscan2
- IGSF11 | c.1023G>T p.L341F (on ENST00000393775 / NM_001015887.3; = p.L340F on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 142/330 reads (43%) | SIFT tolerated (0.74); PolyPhen benign (0.271); catalogued as COSV100677929; called by muse, mutect2, varscan2
- IKZF1 | c.158T>G p.V53G | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.042); catalogued as COSV100498771; called by muse, mutect2, varscan2
- IL22RA2 | c.403G>C p.V135L | Missense Mutation (SNP) | VAF 66/220 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99760841; called by muse, mutect2, varscan2
- IMPG2 | c.3181T>C p.C1061R | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99516575; called by muse, mutect2, varscan2
- IPO4 | c.1667G>C p.G556A | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as COSV99938304; called by mutect2, varscan2
- ITGA11 | c.88C>G p.P30A | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV100242234; called by muse, mutect2, varscan2
- ITGA6 | c.1661C>G p.S554* (on ENST00000442250; = p.S515* on NM_000210.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | catalogued as COSV99906136; called by muse, mutect2
- ITGA8 | c.221T>C p.L74S | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100959790; called by muse, mutect2, varscan2
- ITGAL | c.2319G>T p.E773D | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.058); catalogued as rs199745524, COSV100776361; called by muse, mutect2, varscan2
- ITGAV | c.2542G>T p.G848* | Nonsense Mutation (SNP) | VAF 40/141 reads (28%) | catalogued as COSV99655709; called by muse, mutect2, varscan2
- ITIH2 | c.1462-2A>G p.X488_splice | Splice Site (SNP) | VAF 16/113 reads (14%) | catalogued as COSV100623450; called by muse, mutect2
- ITPR3 | c.5420A>G p.N1807S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.897); catalogued as rs1315533457, COSV100968157; called by muse, mutect2
- ITSN2 | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV100744207; called by muse, mutect2, varscan2
- IZUMO4 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100643072; called by muse, mutect2, varscan2
- JPH3 | c.1463C>A p.P488Q | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99414062; called by muse, varscan2
- KCNA7 | c.335G>A p.C112Y | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99672041; called by muse, mutect2, varscan2
- KDM3A | c.216G>A p.W72* | Nonsense Mutation (SNP) | VAF 22/114 reads (19%) | catalogued as COSV100461008; called by muse, mutect2, varscan2
- KDM6B | c.4226A>T p.E1409V | Missense Mutation (SNP) | VAF 55/90 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV99642356; called by muse, mutect2, varscan2
- KHDC4 | c.620A>C p.Q207P | Missense Mutation (SNP) | VAF 103/154 reads (67%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.862); catalogued as COSV100850858; called by muse, mutect2, varscan2
- KIAA0232 | c.2953G>T p.G985W | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100301121; called by muse, mutect2, varscan2
- KLHL4 | c.2153C>A p.P718H | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100910217; called by muse, mutect2, varscan2
- KMT2C | c.8310A>T p.K2770N | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100076776; called by muse, mutect2
- KRT12 | c.1373C>A p.T458N | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.369); catalogued as COSV99289147; called by muse, mutect2, varscan2
- KRT12 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); catalogued as rs765293236, COSV99289148; called by muse, mutect2, varscan2
- KRT2 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.311); catalogued as COSV100548668, COSV59011932; called by muse, mutect2, varscan2
- KRT38 | c.962T>C p.L321P | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1367253727, COSV99878403; called by muse, mutect2, varscan2
- KRTAP4-2 | c.316G>A p.G106S | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100894569, COSV66658049; called by muse, mutect2, varscan2
- KRTAP5-1 | c.530G>T p.C177F | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.187); catalogued as COSV101192948; called by muse, mutect2, varscan2
- KRTAP5-6 | c.116G>C p.C39S | Missense Mutation (SNP) | VAF 37/279 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.263); catalogued as COSV101191783; called by muse, mutect2, varscan2
- KRTAP5-7 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 77/377 reads (20%) | PolyPhen benign (0.102); catalogued as COSV101273246; called by muse, mutect2, varscan2
- L1CAM | c.1866C>A p.D622E | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.011); catalogued as COSV100649480; called by muse, mutect2, varscan2
- LACRT | c.59-1G>T p.X20_splice | Splice Site (SNP) | VAF 41/165 reads (25%) | catalogued as COSV57687705; called by muse, mutect2, varscan2
- LAMA1 | c.1451G>T p.R484L | Missense Mutation (SNP) | VAF 59/207 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as COSV101057825, COSV67541379; called by muse, mutect2, varscan2
- LAMC3 | c.3209C>T p.P1070L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100736101; called by muse, mutect2, varscan2
- LAMC3 | c.3564C>A p.Y1188* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as COSV100736102, COSV62654197; called by muse, mutect2, varscan2
- LILRA1 | c.1436T>A p.L479Q | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99252209; called by muse, varscan2
- LRBA | c.1980G>A p.M660I | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100842106; called by muse, mutect2, varscan2
- LRP1 | c.2357G>C p.R786P | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV54525215, COSV99677311; called by muse, mutect2, varscan2
- LRRC30 | c.557A>G p.K186R | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV101274458; called by muse, mutect2, varscan2
- LRRC75B | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 62/348 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV99959353; called by muse, mutect2, varscan2
- LRRTM4 | c.1652A>G p.E551G | Missense Mutation (SNP) | VAF 84/127 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV101299391; called by muse, mutect2, varscan2
- LSM14A | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 66/95 reads (69%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as rs746518009, COSV101471757; called by muse, mutect2, varscan2
- MACF1 | c.11191G>A p.A3731T (on ENST00000372915; = p.A1664T on NM_012090.5) | Missense Mutation (SNP) | VAF 18/36 reads (50%) | catalogued as rs367562249; called by muse, mutect2, varscan2
- MARCHF10 | c.176G>T p.R59I | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV100248636; called by muse, mutect2, varscan2
- MAST4 | c.7196G>A p.R2399Q (on ENST00000403625 / NM_001164664.2; = p.R2210Q on NM_015183.3) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.092); catalogued as rs767673736, COSV99845961; called by muse, varscan2
- MB21D2 | c.502G>C p.V168L | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.065); catalogued as rs1391601209, COSV101165187; called by muse, mutect2, varscan2
- MEGF10 | c.1387G>A p.V463I | Missense Mutation (SNP) | VAF 80/158 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99175703; called by muse, varscan2
- MGAM | c.2228A>T p.H743L | Missense Mutation (SNP) | VAF 104/315 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.839); catalogued as COSV101527770; called by muse, mutect2, varscan2
- MGAM | c.3376C>A p.L1126I | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV101527771; called by muse, mutect2, varscan2
- MGAT5B | c.1595G>T p.G532V (on ENST00000569840 / NM_001199172.2; = p.G530V on NM_144677.3) | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100048990; called by muse, mutect2, varscan2
- MIA3 | c.911A>T p.D304V | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as COSV100719542; called by muse, mutect2, varscan2
- MKS1 | c.1445C>T p.T482I | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs962001500, COSV99836790; called by muse, mutect2, varscan2
- MOG | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 96/197 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100973150; called by muse, mutect2, varscan2
- MREG | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 29/68 reads (43%) | catalogued as rs764144154, COSV54373560; called by muse, mutect2, varscan2
- MSMP | c.108C>G p.S36R | Missense Mutation (SNP) | VAF 142/343 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV100960381; called by muse, mutect2, varscan2
- MTFR2 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100886750; called by muse, mutect2
- MTMR10 | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as COSV100076377; called by muse, mutect2, varscan2
- MTUS2 | c.2800C>A p.P934T | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1242292179, COSV99686656; called by muse, mutect2
- MUC16 | c.38923C>T p.R12975W | Missense Mutation (SNP) | VAF 68/215 reads (32%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs377388093; called by muse, mutect2, varscan2
- MUC16 | c.15536A>G p.N5179S | Missense Mutation (SNP) | VAF 85/351 reads (24%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV67480645; called by muse, mutect2
- MUC7 | c.307C>A p.P103T | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.138); catalogued as COSV100512394; called by muse, mutect2, varscan2
- MYEF2 | c.453A>T p.E151D | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV99982215; called by muse, mutect2, varscan2
- MYH13 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs760092709, COSV99355533; called by muse, mutect2, varscan2
- MYH6 | c.3992T>A p.L1331Q | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100677025; called by muse, mutect2, varscan2
- MYL12A | c.196G>C p.D66H | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV54182489, COSV99470269; called by muse, mutect2
- MYO1F | c.769C>A p.L257M | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as COSV100597105; called by muse, mutect2, varscan2
- N4BP2 | c.3687G>C p.K1229N | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs755937987, COSV99789311; called by muse, mutect2, varscan2
- NAP1L4 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 23/80 reads (29%) | catalogued as COSV101000759, COSV65882425; called by muse, mutect2, varscan2
- NEUROD2 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1179457020, COSV100223220; called by muse, mutect2, varscan2
- NKAIN3 | c.403G>A p.V135I | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.224); catalogued as COSV100136704; called by muse, mutect2, varscan2
- NOS3 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as rs750857933, COSV52498168; called by muse, mutect2, varscan2
- NPBWR1 | c.482C>A p.A161D | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs1370176276, COSV100488312; called by muse, mutect2, varscan2
- NRG3 | c.2078C>A p.P693H (on ENST00000404547 / NM_001370084.1; = p.P669H on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100930813; called by muse, mutect2, varscan2
- NSD1 | c.4894G>T p.G1632C | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV61785773; called by muse, mutect2, varscan2
- NUMB | c.198A>T p.K66N | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV100680053; called by muse, mutect2, varscan2
- NUTM2G | c.1183C>A p.P395T | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV100672976; called by muse, mutect2, varscan2
- NXPH1 | c.586A>G p.I196V | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV101339824; called by muse, mutect2, varscan2
- OAZ2 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as rs369960638, COSV100386473; called by muse, mutect2
- OLFM1 | c.844G>A p.D282N (on ENST00000371793 / NM_001282611.2; = p.D264N on NM_014279.5) | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV53281873; called by muse, mutect2, varscan2
- OR10G8 | c.338T>G p.L113R | Missense Mutation (SNP) | VAF 105/172 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101461885; called by muse, mutect2, varscan2
- OR10H1 | c.838A>T p.T280S | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV100612508; called by muse, mutect2, varscan2
- OR10X1 | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63768046; called by muse, mutect2, varscan2
- OR11H1 | c.486C>G p.I162M | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV99421614; called by mutect2, varscan2
- OR11H12 | c.634C>A p.L212M | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.35); catalogued as rs1380352019, COSV73569097; called by mutect2, varscan2
- OR2L3 | c.40T>A p.L14I | Missense Mutation (SNP) | VAF 36/390 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs891719294, COSV100742060; called by muse, mutect2
- OR2L8 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 57/321 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV100594330; called by muse, mutect2, varscan2
- OR4C12 | c.843T>A p.N281K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV100078696; called by muse, mutect2, varscan2
- OR4L1 | c.854G>A p.S285N | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100235923; called by muse, mutect2, varscan2
- OR51E2 | c.555G>T p.K185N | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.078); catalogued as rs1564885069, COSV101211407; called by muse, mutect2, varscan2
- OR5H2 | c.808C>A p.P270T | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.014); catalogued as COSV100788842; called by muse, mutect2
- OR5K4 | c.352A>G p.M118V | Missense Mutation (SNP) | VAF 305/540 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV100721409; called by muse, mutect2, varscan2
- OR8B4 | c.607G>T p.G203* | Nonsense Mutation (SNP) | VAF 26/48 reads (54%) | catalogued as COSV100635840; called by muse, mutect2, varscan2
- OTOF | c.2755A>C p.S919R (on ENST00000272371 / NM_194248.3; = p.S172R on NM_004802.4) | Missense Mutation (SNP) | VAF 64/105 reads (61%) | SIFT tolerated (0.13); PolyPhen benign (0.147); catalogued as COSV55496879, COSV99719051; called by muse, mutect2, varscan2
- OVCH1 | c.1284A>T p.E428D | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.176); catalogued as COSV100549250; called by muse, mutect2, varscan2
- PCDHA4 | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.988); catalogued as COSV100793765; called by muse, mutect2, varscan2
- PCDHA5 | c.103C>A p.P35T | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.083); catalogued as COSV100972248, COSV65355295; called by muse, mutect2, varscan2
- PCDHA8 | c.114G>C p.E38D | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV100971045; called by muse, mutect2, varscan2
- PCDHB5 | c.497C>G p.T166S | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.01); catalogued as COSV99169614; called by muse, mutect2, varscan2
- PCLO | c.3541T>A p.S1181T | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.234); catalogued as COSV100438121; called by muse, mutect2, varscan2
- PECR | c.290C>G p.T97S | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99526991; called by muse, mutect2, varscan2
- PEG3 | c.4097C>A p.A1366D | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV55629464, COSV99690513; called by muse, mutect2, varscan2
- PHLDB1 | c.1773G>T p.E591D | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); catalogued as COSV100616801; called by muse, mutect2, varscan2
- PHLDB2 | c.1325T>A p.M442K | Missense Mutation (SNP) | VAF 179/301 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV101208722; called by muse, mutect2, varscan2
- PIK3R3 | c.451A>T p.K151* | Nonsense Mutation (SNP) | VAF 118/225 reads (52%) | catalogued as COSV99422948; called by muse, mutect2, varscan2
- PIKFYVE | c.5989G>T p.V1997L | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV100011491; called by muse, mutect2, varscan2
- PIP5K1A | c.468C>G p.I156M (on ENST00000368888 / NM_001135638.2; = p.I143M on NM_003557.3) | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV100576765; called by muse, mutect2, varscan2
- PIP5K1A | c.992A>G p.N331S (on ENST00000368888 / NM_001135638.2; = p.N318S on NM_003557.3) | Missense Mutation (SNP) | VAF 45/66 reads (68%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as rs754456936, COSV100576768; called by muse, mutect2, varscan2
- PIP5K1B | c.1253A>T p.K418M | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV99599848; called by muse, mutect2, varscan2
- PJA1 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100824819; called by muse, mutect2, varscan2
- PLA1A | c.195G>C p.Q65H | Missense Mutation (SNP) | VAF 78/364 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV99846096; called by muse, mutect2, varscan2
- PLA1A | c.1129C>T p.Q377* | Nonsense Mutation (SNP) | VAF 20/174 reads (11%) | catalogued as COSV99846099; called by muse, mutect2, varscan2
- PLEC | c.4027G>T p.G1343C (on ENST00000322810 / NM_201380.4; = p.G1233C on NM_000445.5) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1564082698, COSV100519243; called by muse, mutect2, varscan2
- PLXDC2 | c.1217T>C p.L406P | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV101023294; called by muse, mutect2, varscan2
- PLXNA4 | c.2994G>T p.R998S | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.375); catalogued as COSV100327271, COSV58126176; called by muse, mutect2, varscan2
- PLXNA4 | c.2994-1G>T p.X998_splice | Splice Site (SNP) | VAF 20/95 reads (21%) | catalogued as COSV100327274; called by muse, mutect2, varscan2
- PPP1CB | c.504C>G p.I168M | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV99941985; called by muse, mutect2, varscan2
- PPP2R3B | c.1085+1G>T p.X362_splice | Splice Site (SNP) | VAF 48/121 reads (40%) | catalogued as COSV101180807; called by muse, mutect2, varscan2
- PRKDC | c.696C>G p.C232W | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.405); catalogued as COSV100043032; called by muse, mutect2
- PROK2 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.097); catalogued as COSV99817087; called by muse, mutect2, varscan2
- PSG9 | c.558C>A p.S186R | Missense Mutation (SNP) | VAF 36/358 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as rs749827661, COSV99392585; called by muse, mutect2, varscan2
- PSIP1 | c.1343G>C p.R448T | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV101051011; called by muse, mutect2, varscan2
- PTGDS | c.381G>T p.Q127H | Missense Mutation (SNP) | VAF 66/191 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99812077; called by muse, mutect2, varscan2
- PTGFRN | c.1945G>T p.D649Y | Missense Mutation (SNP) | VAF 65/126 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101277463; called by muse, mutect2, varscan2
- PTPN11 | c.119A>G p.D40G | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.324); catalogued as rs397516795, COSV100692877; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPN14 | c.637G>T p.D213Y | Missense Mutation (SNP) | VAF 86/160 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100872958; called by muse, mutect2, varscan2
- PTPRN | c.2514C>A p.N838K | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV55350882; called by muse, mutect2, varscan2
- PTPRN2 | c.2236G>C p.E746Q | Missense Mutation (SNP) | VAF 64/435 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as rs1285185217, COSV101235393; called by muse, mutect2, varscan2
- PUS1 | c.221A>G p.D74G | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100435294; called by muse, varscan2
- PYCARD | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99910971; called by muse, mutect2
- QSER1 | c.5145G>T p.W1715C (on ENST00000399302; = p.W1844C on NM_001076786.3) | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV101234970; called by muse, mutect2, varscan2
- RAB42 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.102); catalogued as rs370099619; called by muse, mutect2, varscan2
- RAD54L2 | c.2035A>T p.T679S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV99621880; called by muse, mutect2, varscan2
- RBM15B | c.577G>C p.A193P | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100082369; called by muse, mutect2, varscan2
- RELN | c.4355A>G p.D1452G | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.273); catalogued as COSV100634961; called by muse, mutect2, varscan2
- RELN | c.928A>T p.I310F | Missense Mutation (SNP) | VAF 94/192 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV100634962; called by muse, mutect2, varscan2
- RFX3 | c.925G>T p.V309F | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as COSV100175913; called by muse, mutect2, varscan2
- RGS3 | c.3107G>T p.G1036V (on ENST00000350696 / NM_001282923.2; = p.G755V on NM_130795.4) | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV100637031, COSV59520397; called by muse, mutect2, varscan2
- RNF19A | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 82/212 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs764778067, COSV61993180; called by muse, mutect2, varscan2
- ROS1 | c.5249C>A p.A1750D | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV100876414, COSV100877723; called by muse, mutect2, varscan2
- ROS1 | c.3103C>G p.R1035G | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV100877724, COSV63852375; called by muse, mutect2, varscan2
- RPUSD4 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 76/190 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV100028925; called by muse, mutect2, varscan2
- SCCPDH | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100829747; called by muse, mutect2, varscan2
- SCN1B | c.299A>T p.D100V | Missense Mutation (SNP) | VAF 25/238 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99386715; called by muse, mutect2
- SCUBE3 | c.911A>T p.K304M | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV99235270; called by muse, mutect2, varscan2
- SENP6 | c.2879A>T p.Q960L | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100894643; called by muse, mutect2, varscan2
- SENP7 | c.1309G>T p.A437S | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.305); catalogued as COSV100053927; called by muse, mutect2, varscan2
- SFXN4 | c.100A>G p.T34A | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV100045455; called by muse, mutect2, varscan2
- SIGLEC9 | c.100G>C p.G34R | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99143388; called by mutect2, varscan2
- SIRPA | c.509G>A p.C170Y | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100605431; called by muse, mutect2, varscan2
- SLC12A5 | c.1802T>A p.V601E (on ENST00000454036 / NM_001134771.2; = p.V578E on NM_020708.5) | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as COSV99716900; called by muse, mutect2, varscan2
- SLC17A3 | c.116del p.Y39Lfs*3 | Frame Shift Del (DEL) | VAF 50/123 reads (41%) | catalogued as COSV57760453; called by mutect2, pindel, varscan2
- SLC18B1 | c.812G>C p.G271A | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.115); catalogued as COSV99259357; called by muse, mutect2, varscan2
- SLC25A11 | c.529G>T p.V177F | Missense Mutation (SNP) | VAF 173/266 reads (65%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV99337583; called by muse, mutect2, varscan2
- SLC25A40 | c.1017G>C p.*339Yext*1 | Nonstop Mutation (SNP) | VAF 18/59 reads (31%) | catalogued as COSV100353826; called by muse, mutect2, varscan2
- SLC36A3 | c.1017C>A p.F339L | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.261); catalogued as COSV100077488, COSV58856692; called by muse, mutect2, varscan2
- SLCO1B1 | c.728-2A>T p.X243_splice | Splice Site (SNP) | VAF 25/172 reads (15%) | catalogued as COSV99919198; called by muse, mutect2, varscan2
- SMAD2 | c.1370G>C p.G457A | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV100054086; called by muse, mutect2, varscan2
- SNX13 | c.2713A>G p.R905G | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV101296907; called by muse, mutect2, varscan2
- SOGA3 | c.2707G>A p.A903T | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs780610632, COSV64104863; called by muse, mutect2, varscan2
- SOST | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100059797; called by muse, mutect2, varscan2
- SPATA16 | c.758+1G>A p.X253_splice | Splice Site (SNP) | VAF 65/140 reads (46%) | catalogued as COSV100651699; called by muse, mutect2, varscan2
- SPEF2 | c.2114T>C p.L705P | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100608942; called by muse, mutect2, varscan2
- SPOCK3 | c.360-1G>T p.X120_splice | Splice Site (SNP) | VAF 14/28 reads (50%) | catalogued as rs1193237028, COSV62741221; called by muse, mutect2, varscan2
- SRPRA | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as rs779075965, COSV55006894; called by muse, mutect2, varscan2
- STK36 | c.3695A>T p.E1232V | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99831973; called by muse, mutect2, varscan2
- SYDE2 | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as COSV99320664; called by muse, mutect2, varscan2
- SYNE1 | c.10989G>T p.Q3663H (on ENST00000367255 / NM_182961.4; = p.Q3648H on NM_033071.3) | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55044639, COSV99579758; called by muse, mutect2, varscan2
- TAPBP | c.154G>T p.G52W | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as COSV99802699; called by muse, mutect2, varscan2
- TAS2R20 | c.718A>G p.I240V | Missense Mutation (SNP) | VAF 48/207 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as COSV101115656; called by muse, mutect2
- TAS2R39 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs748678979, COSV101489422, COSV71470920; called by muse, mutect2, varscan2
- TBC1D1 | c.741G>T p.R247S | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV99792238; called by muse, mutect2, varscan2
- TBCD | c.2162C>T p.S721F | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV100833782; called by muse, mutect2, varscan2
- TBRG4 | c.1322-1G>T p.X441_splice | Splice Site (SNP) | VAF 18/111 reads (16%) | catalogued as COSV51834051; called by muse, mutect2, varscan2
- TEK | c.1357G>A p.V453M | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.557); catalogued as rs373235916; called by muse, mutect2
- TENM1 | c.8014G>T p.G2672W | Missense Mutation (SNP) | VAF 93/165 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100951026; called by muse, mutect2, varscan2
- TENM1 | c.3304T>C p.S1102P | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100951029; called by muse, mutect2, varscan2
- TERF1 | c.38G>T p.R13L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.995); catalogued as COSV52577713, COSV52579119; called by muse, mutect2, varscan2
- TEX2 | c.2378G>A p.R793K (on ENST00000583097 / NM_001288733.2; = p.R800K on NM_018469.5) | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT tolerated (0.92); PolyPhen benign (0.009); catalogued as rs547970919, COSV99367531; called by muse, mutect2, varscan2
- TFAP2A | c.169C>T p.P57S (on ENST00000482890; = p.P49S on NM_001032280.3) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV100117199; called by muse, varscan2
- THSD7A | c.2089T>A p.Y697N | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101448918; called by muse, mutect2, varscan2
- TINAG | c.749G>T p.S250I | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99450874; called by muse, mutect2, varscan2
- TLN2 | c.2095A>G p.T699A | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100170120; called by muse, mutect2, varscan2
- TMEM131L | c.1346G>C p.G449A | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99548163; called by muse, mutect2, varscan2
- TMEM200C | c.207G>T p.M69I | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV101274867; called by muse, mutect2, varscan2
- TMEM230 | c.109A>C p.T37P | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99177028; called by muse, mutect2, varscan2
- TMF1 | c.2303C>T p.T768I | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV101275470; called by muse, mutect2, varscan2
- TMPRSS7 | c.1522G>T p.D508Y (on ENST00000452346; = p.D382Y on NM_001042575.2) | Missense Mutation (SNP) | VAF 252/537 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101340186; called by muse, mutect2, varscan2
- TNS3 | c.2254G>T p.G752C | Missense Mutation (SNP) | VAF 57/238 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.436); catalogued as COSV100236500; called by muse, mutect2, varscan2
- TOPORS | c.2500G>A p.G834R | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.245); catalogued as COSV100859585; called by muse, mutect2, varscan2
- TOX | c.1168C>G p.P390A | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100789304; called by muse, mutect2, varscan2
- TRIM22 | c.1224G>A p.W408* | Nonsense Mutation (SNP) | VAF 34/114 reads (30%) | catalogued as COSV101181534; called by muse, mutect2, varscan2
- TRPM2 | c.320C>A p.T107N | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100309350; called by muse, mutect2, varscan2
- TTC17 | c.1300G>T p.G434* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as COSV99236088; called by muse, mutect2, varscan2
- TTLL6 | c.1610G>C p.R537T (on ENST00000393382 / NM_001130918.3; = p.R230T on NM_173623.3) | Missense Mutation (SNP) | VAF 118/478 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100938234; called by muse, mutect2, varscan2
- TTN | c.94216A>T p.K31406* (on ENST00000591111; = p.K23982* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 30/492 reads (6%) | catalogued as COSV100631103; called by muse, mutect2
- TTN | c.72314C>A p.S24105* (on ENST00000591111; = p.S16681* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 16/227 reads (7%) | catalogued as COSV100631110; called by muse, mutect2
- TTN | c.49511A>G p.N16504S (on ENST00000591111; = p.N9080S on NM_003319.4) | Missense Mutation (SNP) | VAF 16/80 reads (20%) | PolyPhen probably damaging (0.994); catalogued as COSV100631114; called by muse, mutect2, varscan2
- TTN | c.2200G>T p.E734* (on ENST00000591111; = p.E688* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 31/156 reads (20%) | catalogued as COSV100631122; called by muse, mutect2, varscan2
- TUT7 | c.3616G>T p.V1206F | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99463710; called by muse, mutect2, varscan2
- UBAP2L | c.2612C>T p.S871F | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55168142, COSV55179870; called by muse, mutect2
- UBE2U | c.654G>T p.Q218H | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); catalogued as COSV100934532; called by muse, mutect2, varscan2
- USP21 | c.112C>G p.R38G | Missense Mutation (SNP) | VAF 69/134 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as COSV57087096, COSV99237826; called by muse, mutect2, varscan2
- VAC14 | c.1432G>T p.D478Y | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV99935099; called by muse, mutect2, varscan2
- VCAM1 | c.1117G>T p.V373L | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as COSV99658939; called by muse, mutect2, varscan2
- VEZT | c.1792G>C p.E598Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99704328; called by muse, mutect2, varscan2
- WAC | c.1762G>C p.E588Q | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100611201; called by muse, mutect2, varscan2
- XDH | c.2852G>A p.G951E | Missense Mutation (SNP) | VAF 88/148 reads (59%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as COSV101052478; called by muse, mutect2, varscan2
- XIRP2 | c.5377G>A p.A1793T (on ENST00000628543; = p.A1968T on NM_152381.6) | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.202); catalogued as COSV99747753; called by muse, mutect2, varscan2
- XPNPEP2 | c.119C>A p.P40H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV100941296, COSV64368144; called by muse, mutect2
- XYLT2 | c.2383G>T p.E795* | Nonsense Mutation (SNP) | VAF 19/70 reads (27%) | catalogued as COSV99191185; called by muse, mutect2, varscan2
- ZBTB11 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100465883; called by muse, mutect2, varscan2
- ZFHX4 | c.9615G>C p.E3205D | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.725); catalogued as COSV51471914, COSV99268038; called by muse, mutect2, varscan2
- ZFHX4 | c.9616G>C p.E3206Q | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.189); catalogued as rs765671240, COSV99268039; called by muse, mutect2, varscan2
- ZFR2 | c.1583T>A p.L528Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.696); catalogued as COSV99507924; called by muse, mutect2, varscan2
- ZKSCAN8 | c.735A>T p.R245S | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV100363051; called by muse, mutect2, varscan2
- ZNF341 | c.2356G>T p.E786* (on ENST00000375200 / NM_001282935.1; = p.E779* on NM_032819.4) | Nonsense Mutation (SNP) | VAF 23/71 reads (32%) | catalogued as COSV100677760, COSV100678075; called by muse, mutect2, varscan2
- ZNF365 | c.845T>A p.V282E | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV101237999; called by muse, mutect2, varscan2
- ZNF366 | c.1499C>G p.S500C | Missense Mutation (SNP) | VAF 99/228 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100574516; called by muse, mutect2, varscan2
- ZNF479 | c.887C>A p.P296H | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58639178; called by muse, mutect2, varscan2
- ZNF548 | c.303G>C p.E101D | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.109); catalogued as COSV100278306; called by muse, mutect2, varscan2
- ZNF578 | c.42G>C p.E14D | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.801); catalogued as COSV101405122; called by muse, mutect2, varscan2
- ZNF616 | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs1042870253, COSV100348622; called by muse, mutect2, varscan2
- ZNF616 | c.361G>T p.G121C | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.626); catalogued as COSV100348623; called by muse, mutect2, varscan2
- ZNF676 | c.710C>T p.A237V (on ENST00000650058; = p.A205V on NM_001001411.3) | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.939); catalogued as COSV68092311; called by muse, varscan2
- ZNF676 | c.709G>A p.A237T (on ENST00000650058; = p.A205T on NM_001001411.3) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.804); catalogued as rs769716448, COSV101236224, COSV101236359; called by muse, varscan2
- ZNF770 | c.1514G>T p.C505F | Missense Mutation (SNP) | VAF 66/95 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100696063; called by muse, mutect2, varscan2
- ZNF778 | c.1229G>C p.R410T | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV100124646; called by muse, mutect2, varscan2
- ZNF804A | c.3373C>T p.L1125F | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.088); catalogued as COSV100169880, COSV100170308; called by muse, mutect2
- ZNF804B | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as COSV100306373; called by muse, varscan2
- ZNF804B | c.1300C>A p.H434N | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.368); catalogued as COSV100306377; called by muse, mutect2, varscan2
- ZNF883 | c.817A>G p.T273A | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as COSV101432697; called by muse, mutect2, varscan2
- ATXN2 | c.1732del p.A578Qfs*70 (on ENST00000550104; = p.A418Qfs*70 on NM_002973.4) | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | called by mutect2, pindel
- CCDC9B | c.939del p.Q314Kfs*21 | Frame Shift Del (DEL) | VAF 17/65 reads (26%) | called by mutect2, pindel, varscan2
- COPS3 | c.421dup p.I141Nfs*4 | Frame Shift Ins (INS) | VAF 20/96 reads (21%) | called by mutect2, pindel, varscan2
- DICER1 | c.5199_5212del p.D1734Pfs*26 | Frame Shift Del (DEL) | VAF 59/156 reads (38%) | called by mutect2, pindel, varscan2
- EFCAB3 | c.252del p.K85Sfs*8 | Frame Shift Del (DEL) | VAF 40/167 reads (24%) | called by mutect2, pindel, varscan2
- FRMPD1 | c.84_95del p.R29_S32del | In Frame Del (DEL) | VAF 16/118 reads (14%) | called by mutect2, pindel
- HDAC6 | c.1275del p.C426Vfs*14 | Frame Shift Del (DEL) | VAF 8/61 reads (13%) | called by mutect2, pindel, varscan2
- HNMT | c.570del p.Q192Rfs*20 | Frame Shift Del (DEL) | VAF 18/79 reads (23%) | called by mutect2, pindel, varscan2
- IGKV1D-42 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- KMT2D | c.8223del p.T2742Hfs*15 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | called by mutect2, pindel, varscan2
- LILRB3 | c.335C>A p.P112H | Missense Mutation (SNP) | VAF 53/323 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- LRRTM3 | c.1228dup p.A410Gfs*2 | Frame Shift Ins (INS) | VAF 15/70 reads (21%) | called by mutect2, pindel, varscan2
- MDN1 | c.2107_2112del p.M703_N704del | In Frame Del (DEL) | VAF 14/100 reads (14%) | called by mutect2, pindel, varscan2
- MMP16 | c.864del p.I289Yfs*62 | Frame Shift Del (DEL) | VAF 40/127 reads (31%) | called by mutect2, pindel, varscan2
- MSH6 | c.72_83del p.A25_S28del | In Frame Del (DEL) | VAF 18/79 reads (23%) | called by mutect2, pindel, varscan2
- MUC2 | c.635G>A p.G212D | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.18); called by muse, mutect2, varscan2
- PRC1 | c.676del p.E226Kfs*52 | Frame Shift Del (DEL) | VAF 19/117 reads (16%) | called by mutect2, pindel, varscan2
- TKTL2 | c.630dup p.G211Wfs*11 | Frame Shift Ins (INS) | VAF 31/77 reads (40%) | called by mutect2, pindel, varscan2
- UBE2NL | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 76/111 reads (68%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- USH2A | c.8729_8745delinsGT p.F2910_E2915delinsC | In Frame Del (DEL) | VAF 20/49 reads (41%) | called by pindel, varscan2*
- ZNF658 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- A1BG | c.510C>T p.A170= | Silent (SNP) | VAF 75/264 reads (28%) | catalogued as COSV99568701; called by muse, mutect2, varscan2
- ABCF3 | c.627G>T p.V209= | Silent (SNP) | VAF 25/182 reads (14%) | catalogued as COSV99490977; called by muse, mutect2, varscan2
- ACACB | c.645C>G p.P215= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV100623312; called by muse, mutect2, varscan2
- ACAN | c.1008C>G p.G336= | Silent (SNP) | VAF 17/117 reads (15%) | catalogued as COSV100719341; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1944C>T p.C648= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as rs531964438, COSV99444995; called by muse, mutect2, varscan2
- ADAP2 | c.1050G>A p.Q350= | Silent (SNP) | VAF 31/100 reads (31%) | catalogued as rs1190634929, COSV100437370; called by muse, mutect2, varscan2
- ADCY8 | c.3222A>T p.I1074= | Silent (SNP) | VAF 57/90 reads (63%) | catalogued as COSV99654493; called by muse, mutect2, varscan2
- AFG1L | c.1428A>T p.G476= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV100934025; called by muse, mutect2, varscan2
- AL121899.2 | c.222G>A p.E74= | Silent (SNP) | VAF 22/178 reads (12%) | catalogued as COSV101198695; called by muse, mutect2, varscan2
- ALMS1 | c.2679A>C p.P893= | Silent (SNP) | VAF 125/174 reads (72%) | catalogued as COSV100043833; called by muse, mutect2, varscan2
- ALOXE3 | c.1236G>C p.T412= | Silent (SNP) | VAF 28/43 reads (65%) | catalogued as COSV100559986; called by muse, mutect2, varscan2
- ANAPC5 | c.843G>C p.L281= | Silent (SNP) | VAF 70/200 reads (35%) | catalogued as COSV99946515; called by muse, mutect2, varscan2
- APOA4 | c.612C>T p.Y204= | Silent (SNP) | VAF 195/322 reads (61%) | catalogued as rs201385362, COSV63361128; called by muse, mutect2, varscan2
- APOH | c.348G>A p.L116= | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as COSV52771389; called by muse, mutect2
- ART4 | c.204C>T p.G68= | Silent (SNP) | VAF 11/222 reads (5%) | catalogued as rs1379360965, COSV99966995; called by muse, mutect2
- ATP5MC2 | c.216C>T p.A72= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as COSV100101072; called by muse, mutect2, varscan2
- ATXN2L | c.3081C>G p.P1027= | Silent (SNP) | VAF 42/109 reads (39%) | catalogued as rs747031718, COSV100295234, COSV57367537; called by muse, mutect2, varscan2
- AUP1 | c.336C>T p.S112= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV99239962; called by muse, varscan2
- AUP1 | c.231C>T p.A77= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV99239963; called by muse, varscan2
- BPIFB6 | c.1173G>A p.S391= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as rs761723770, COSV100848487, COSV100848557; called by muse, mutect2, varscan2
- BRF1 | c.993A>G p.E331= | Silent (SNP) | VAF 14/236 reads (6%) | catalogued as rs757619665, COSV100527799; called by muse, mutect2
- C3 | c.1938C>T p.F646= | Silent (SNP) | VAF 44/146 reads (30%) | catalogued as COSV99837287; called by muse, mutect2, varscan2
- CA12 | c.630G>A p.L210= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as rs766031071, COSV99458800; called by muse, mutect2, varscan2
- CALHM5 | c.300C>A p.L100= | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as COSV100635669; called by muse, mutect2, varscan2
- CALN1 | c.642C>A p.L214= (on ENST00000329008 / NM_001017440.3; = p.L256= on NM_031468.4) | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV100209539; called by muse, mutect2, varscan2
- CCDC172 | c.738G>A p.E246= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV100320018; called by muse, mutect2, varscan2
- CDON | c.1275C>T p.S425= | Silent (SNP) | VAF 20/114 reads (18%) | catalogued as COSV99702025; called by muse, mutect2, varscan2
- CFAP43 | c.1626G>T p.S542= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV99530594, COSV99531031; called by muse, mutect2, varscan2
- CFAP61 | c.2763C>A p.T921= | Silent (SNP) | VAF 51/348 reads (15%) | catalogued as COSV99846719; called by muse, mutect2, varscan2
- CHD8 | c.822A>G p.T274= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV101303221; called by muse, mutect2
- CLCN1 | c.1044A>T p.L348= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as CD1313467, COSV100578562; called by muse, mutect2, varscan2
- CLVS1 | c.645C>T p.A215= | Silent (SNP) | VAF 69/327 reads (21%) | catalogued as COSV100370732; called by muse, mutect2, varscan2
- CNOT2 | c.564G>A p.V188= | Silent (SNP) | VAF 31/134 reads (23%) | catalogued as COSV99973159; called by muse, mutect2, varscan2
- COL6A6 | c.96G>C p.V32= | Silent (SNP) | VAF 15/318 reads (5%) | catalogued as COSV100650979; called by muse, mutect2
- CP | c.261G>A p.P87= | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as rs142440055; called by muse, mutect2, varscan2
- CRHR1 | c.108C>A p.A36= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV99524194; called by muse, mutect2
- CSMD2 | c.6165C>T p.T2055= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs1342501922, COSV99595682; called by muse, mutect2, varscan2
- DIDO1 | c.1914A>T p.V638= | Silent (SNP) | VAF 81/131 reads (62%) | catalogued as COSV99827218; called by muse, mutect2, varscan2
- DIXDC1 | c.225C>A p.P75= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV101098734, COSV101098870; called by muse, mutect2, varscan2
- DTL | c.1809A>G p.L603= | Silent (SNP) | VAF 67/109 reads (61%) | catalogued as COSV100877286; called by muse, mutect2, varscan2
- EHMT2 | c.78G>T p.L26= | Silent (SNP) | VAF 56/124 reads (45%) | catalogued as COSV100977048; called by muse, varscan2
- ELAVL4 | c.1038C>A p.T346= | Silent (SNP) | VAF 32/89 reads (36%) | catalogued as COSV100836915; called by muse, mutect2, varscan2
- ESR1 | c.1671G>C p.G557= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as rs758015198, COSV99241320; called by muse, mutect2, varscan2
- FABP1 | c.81G>A p.E27= | Silent (SNP) | VAF 33/246 reads (13%) | catalogued as COSV99860979; called by muse, mutect2, varscan2
- FAM184A | c.1224G>C p.S408= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV100138392; called by muse, mutect2, varscan2
- FAM83C | c.981G>T p.V327= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100981719; called by muse, mutect2
- FHDC1 | c.1977G>A p.Q659= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV99471721; called by muse, mutect2, varscan2
- FHL5 | c.273G>T p.T91= | Silent (SNP) | VAF 32/131 reads (24%) | catalogued as COSV100459820, COSV58735839; called by muse, mutect2, varscan2
- FOXN3 | c.1140C>T p.S380= (on ENST00000261302; = p.S358= on NM_005197.4) | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as rs375910548; called by muse, varscan2
- FOXRED2 | c.345G>T p.S115= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as COSV99341129; called by muse, mutect2, varscan2
- GABRR2 | c.90G>A p.G30= | Silent (SNP) | VAF 26/480 reads (5%) | catalogued as COSV101299045; called by muse, mutect2
- GRM4 | c.483C>G p.V161= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV100946912; called by muse, mutect2, varscan2
- H1-3 | c.291C>T p.T97= | Silent (SNP) | VAF 29/162 reads (18%) | catalogued as rs955234705, COSV55097479; called by muse, mutect2, varscan2
- HDC | c.711G>T p.V237= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV99984339; called by muse, mutect2, varscan2
- HECW1 | c.3657C>A p.A1219= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as COSV101222977; called by muse, mutect2, varscan2
- HTR3B | c.246A>G p.V82= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as rs746993257, COSV99492333; called by muse, mutect2, varscan2
- IGLL5 | c.525G>T p.A175= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as COSV101138635, COSV101138979; called by muse, mutect2, varscan2
- KDM7A | c.1479A>T p.P493= | Silent (SNP) | VAF 57/192 reads (30%) | catalogued as COSV99135173; called by muse, mutect2, varscan2
- KLHL34 | c.798G>T p.P266= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as COSV101070004; called by muse, mutect2, varscan2
- LPIN3 | c.726C>T p.S242= | Silent (SNP) | VAF 30/62 reads (48%) | catalogued as rs1331758445, COSV100953144; called by muse, mutect2, varscan2
- LRRC75B | c.660G>A p.L220= | Silent (SNP) | VAF 56/170 reads (33%) | catalogued as rs185762510, COSV99959352; called by muse, mutect2, varscan2
- LRRTM1 | c.1521T>C p.Y507= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as COSV54440371; called by muse, mutect2, varscan2
- MAN1A1 | c.1860C>T p.D620= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as rs781330587, COSV63788592; called by muse, mutect2, varscan2
- MCM3AP | c.3318C>T p.Y1106= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as rs558735247, COSV99386918; called by muse, mutect2, varscan2
- MME | c.1407T>G p.A469= | Silent (SNP) | VAF 13/134 reads (10%) | catalogued as COSV100852552; called by muse, mutect2
- MYBPC3 | c.2541C>T p.Y847= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as rs397515974, CM043545, COSV99920990, COSV99921105; called by muse, mutect2, varscan2
- NDST4 | c.1476C>A p.P492= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV99995549, COSV99997963; called by muse, mutect2, varscan2
- NETO1 | c.663T>C p.Y221= | Silent (SNP) | VAF 40/145 reads (28%) | catalogued as COSV100199797; called by muse, mutect2, varscan2
- NFKB1 | c.1287G>C p.G429= (on ENST00000394820 / NM_001382627.1; = p.G430= on NM_003998.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 16/24 reads (67%) | catalogued as COSV99897918; called by muse, mutect2, varscan2
- NOS3 | c.1458G>A p.K486= | Silent (SNP) | VAF 30/465 reads (6%) | catalogued as COSV99871011, COSV99872196; called by muse, mutect2
- NOTCH2 | c.6324C>T p.A2108= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV99866878; called by muse, mutect2, varscan2
- NWD1 | c.924C>T p.V308= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as COSV100343754; called by muse, mutect2, varscan2
- OR10G8 | c.339C>A p.L113= | Silent (SNP) | VAF 103/172 reads (60%) | catalogued as COSV101461886; called by muse, mutect2, varscan2
- OR10Z1 | c.276C>T p.I92= | Silent (SNP) | VAF 200/339 reads (59%) | catalogued as rs1289173332, COSV100779088; called by muse, mutect2, varscan2
- OR52E6 | c.261C>T p.F87= | Silent (SNP) | VAF 38/157 reads (24%) | catalogued as COSV100259565; called by muse, mutect2, varscan2
- OR52J3 | c.654G>T p.S218= | Silent (SNP) | VAF 45/225 reads (20%) | catalogued as COSV66747742; called by muse, mutect2, varscan2
- OR5H2 | c.807T>G p.S269= | Silent (SNP) | VAF 14/140 reads (10%) | catalogued as rs777874035, COSV100788841; called by muse, mutect2, varscan2
- PDGFD | c.651T>C p.F217= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV100160965; called by muse, mutect2, varscan2
- PFKFB2 | c.1260C>T p.I420= | Silent (SNP) | VAF 15/154 reads (10%) | catalogued as COSV100892051; called by muse, mutect2, varscan2
- PGD | c.807C>T p.I269= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV99581747; called by muse, mutect2
- PHLPP1 | c.1662G>A p.V554= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV99409278; called by muse, mutect2, varscan2
- PLCG2 | c.1086C>T p.D362= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as rs375876385; called by muse, mutect2, varscan2
- PLEKHH1 | c.3447G>A p.E1149= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs762702331, COSV100233496; called by muse, mutect2
- PLPPR4 | c.1515G>A p.Q505= | Silent (SNP) | VAF 74/324 reads (23%) | catalogued as rs148412092, COSV64565018; called by muse, mutect2, varscan2
- PMP2 | c.201A>T p.L67= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as COSV99808347; called by muse, mutect2, varscan2
- POP1 | c.2019G>T p.A673= | Silent (SNP) | VAF 37/112 reads (33%) | catalogued as COSV100855644, COSV100856118; called by muse, mutect2, varscan2
- PPP1R26 | c.2622A>C p.P874= | Silent (SNP) | VAF 48/130 reads (37%) | catalogued as COSV100778162; called by muse, mutect2, varscan2
- PRKD1 | c.2580C>A p.I860= | Silent (SNP) | VAF 48/177 reads (27%) | catalogued as COSV100121615; called by muse, mutect2, varscan2
- PROX1 | c.87A>T p.T29= | Silent (SNP) | VAF 60/94 reads (64%) | catalogued as COSV99800251; called by muse, mutect2, varscan2
- RGS3 | c.3108G>T p.G1036= (on ENST00000350696 / NM_001282923.2; = p.G755= on NM_130795.4) | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as COSV100637035; called by muse, mutect2, varscan2
- RNF213 | c.7398G>A p.E2466= | Silent (SNP) | VAF 42/132 reads (32%) | catalogued as rs746424283, COSV100301568; called by muse, mutect2, varscan2
- RYR1 | c.5244T>G p.P1748= | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as COSV100617067; called by muse, mutect2
- SARDH | c.63G>C p.R21= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV100061278; called by muse, mutect2, varscan2
- SCML1 | c.912G>A p.L304= (on ENST00000380041 / NM_001037540.3; = p.L277= on NM_006746.6) | Silent (SNP) | VAF 49/95 reads (52%) | catalogued as COSV101193987; called by muse, mutect2, varscan2
- SEL1L | c.330A>T p.V110= | Silent (SNP) | VAF 58/196 reads (30%) | catalogued as COSV100378123; called by muse, mutect2, varscan2
- SGSH | c.1323G>T p.R441= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV58341023; called by muse, mutect2, varscan2
- SLITRK2 | c.1533G>T p.V511= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as COSV100158241; called by muse, mutect2, varscan2
- SMARCD3 | c.1449C>A p.T483= (on ENST00000262188 / NM_001003801.2; = p.T470= on NM_003078.4) | Silent (SNP) | VAF 15/229 reads (7%) | catalogued as COSV99223359; called by muse, mutect2
- STARD8 | c.3039C>T p.T1013= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as rs767914896, COSV99367680; called by muse, varscan2
- STK19 | c.978C>A p.L326= (on ENST00000375333 / NM_032454.1; = p.L322= on NM_004197.1) | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV100941721, COSV100941782; called by muse, mutect2
- SUCO | c.759C>T p.D253= | Silent (SNP) | VAF 64/127 reads (50%) | catalogued as COSV99743885; called by muse, mutect2, varscan2
- SVOPL | c.900G>T p.L300= (on ENST00000419765; = p.L148= on NM_174959.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV99939703; called by muse, mutect2, varscan2
- TMEM120B | c.75G>T p.T25= | Silent (SNP) | VAF 21/144 reads (15%) | catalogued as rs756652993, COSV100699714, COSV61184659; called by muse, mutect2, varscan2
- TMEM63C | c.1317C>T p.V439= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as COSV100029817; called by muse, mutect2, varscan2
- TRIM69 | c.981G>A p.L327= (on ENST00000329464 / NM_182985.5; = p.L168= on NM_080745.5) | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV100274424; called by muse, mutect2, varscan2
- TRPC1 | c.1782G>A p.L594= (on ENST00000476941 / NM_001251845.2; = p.L560= on NM_003304.4) | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV99859380; called by muse, mutect2, varscan2
- TTN | c.94215G>A p.K31405= (on ENST00000591111; = p.K23981= on NM_003319.4) | Silent (SNP) | VAF 30/494 reads (6%) | catalogued as COSV100631105; called by muse, mutect2
- USP29 | c.54G>A p.G18= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as rs1002852961, COSV99572522; called by muse, mutect2, varscan2
- XPO6 | c.141C>T p.F47= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV100485386; called by muse, mutect2, varscan2
- ZNF253 | c.1431A>T p.R477= | Silent (SNP) | VAF 34/109 reads (31%) | catalogued as COSV100849596; called by muse, mutect2, varscan2
- ZNF398 | c.1380C>T p.C460= (on ENST00000475153 / NM_170686.3; = p.C289= on NM_020781.4) | Silent (SNP) | VAF 38/134 reads (28%) | catalogued as rs199853265, COSV60065568; called by muse, mutect2, varscan2
- ZNF556 | c.1191T>G p.P397= | Silent (SNP) | VAF 41/138 reads (30%) | catalogued as COSV100298934; called by muse, mutect2, varscan2
- ZNF705A | c.249C>T p.A83= | Silent (SNP) | VAF 35/250 reads (14%) | catalogued as COSV100828370; called by muse, mutect2, varscan2
- ZNF804A | c.3372G>T p.V1124= | Silent (SNP) | VAF 7/114 reads (6%) | catalogued as COSV56478431; called by muse, mutect2
- ZNF835 | c.939G>T p.A313= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV101606408; called by muse, varscan2
- ARHGEF25 | chr12:57620384 G>C | 3'Flank (SNP) | VAF 147/676 reads (22%) | catalogued as COSV99678308; called by muse, mutect2, varscan2
- C9orf129 | n.606A>T | RNA (SNP) | VAF 44/104 reads (42%) | catalogued as COSV100962535; called by muse, mutect2, varscan2
- DENND10P1 | n.619C>A | RNA (SNP) | VAF 73/120 reads (61%) | called by muse, mutect2, varscan2
- IFITM1 | c.-1G>A | 5'UTR (SNP) | VAF 24/102 reads (24%) | catalogued as COSV100068331; called by muse, mutect2, varscan2
- KRT18P55 | n.1260G>T | RNA (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- MAP2K4 | c.393+464G>T | Intron (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100796538; called by muse, varscan2
- MUC2 | chr11:1099725 A>G | 5'Flank (SNP) | VAF 24/94 reads (26%) | called by muse, mutect2
- NAA38 | c.81+38C>G | Intron (SNP) | VAF 22/161 reads (14%) | catalogued as rs753503532, COSV99642363; called by muse, mutect2, varscan2
- PNCK | chrX:153674089 G>T | 5'Flank (SNP) | VAF 17/28 reads (61%) | catalogued as COSV100562508; called by muse, mutect2, varscan2
- SNORD116-1 | n.36G>C | RNA (SNP) | VAF 33/303 reads (11%) | called by muse, mutect2, varscan2
- TRIM36 | c.63+2144G>T | Intron (SNP) | VAF 33/78 reads (42%) | catalogued as COSV99142716; called by muse, mutect2, varscan2
- TTN | c.10360+5529C>A | Intron (SNP) | VAF 76/160 reads (48%) | catalogued as COSV100631121; called by muse, mutect2, varscan2
- WNT16 | chr7:121325415 ins ACCA | 5'Flank (INS) | VAF 40/199 reads (20%) | catalogued as CI133474; called by mutect2, pindel, varscan2
- XIST | n.7407C>A | RNA (SNP) | VAF 59/117 reads (50%) | called by muse, mutect2, varscan2
